TCGA case TCGA-32-4209 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital (AZ). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5438322c-9db0-4974-ba01-801020559f97

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 40 years; Vital status: Dead; Days to death: 618 days (1.7 years).

Diagnoses (4)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 40.8 years (14,903 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 85 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 85 days; Number of cycles: 1; Treatment dose: 75 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 365 days (1.0 years); Days to treatment end: 385 days (1.1 years); Treatment dose: 3,900 cGy; Course number: 2; Number of fractions: 13; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Recurrent Disease; Days to treatment start: 461 days (1.3 years); Days to treatment end: 461 days (1.3 years); Treatment dose: 1,400 cGy; Course number: 3; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 503 days (1.4 years); Days to treatment end: 553 days (1.5 years); Number of cycles: 4; Treatment dose: 400 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 503 days (1.4 years); Days to treatment end: 532 days (1.5 years); Number of cycles: 2; Treatment dose: 200 mg; Prescribed dose: 100; Prescribed dose units: mg/kg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, Cyberknife; Treatment intent type: Palliative; Days to treatment start: 556 days (1.5 years); Days to treatment end: 556 days (1.5 years); Treatment dose: 3,900 cGy; Course number: 4; Number of fractions: 4; Treatment anatomic sites: Regional Site.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 41.1 years (14,997 days); Days to diagnosis: 94 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 94 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.
3. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 41.7 years (15,241 days); Days to diagnosis: 338 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 338 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
4. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.0 years (15,339 days); Days to diagnosis: 436 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 436 days (1.2 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (7 entries)
- Day 94 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 94 days.
- Day 338 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional.
- Day 436 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional.
- Days to follow up: 594 days (1.6 years); Disease response: With Tumor.
- Days to follow up: 604 days (1.7 years); Disease response: With Tumor.
- Days to follow up: 618 days (1.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-32-4209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-32-4209-01A-01-BS1: Section location: Bottom; Percent tumor cells: 97; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0.
  Slide TCGA-32-4209-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0.
- Sample TCGA-32-4209-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Treated primary GBM; History lgg diagnosis of brain tissue: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 03; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Radiation treatment 2: Radiation type other: Cyberknife.
- Radiation treatment 3: Radiation type other: Gamma Knife.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: Per enrollment form, patient had a prior diagnosis of a lower grade glioma. Current TCGA tissue is reported as treated tissue.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 618 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 618 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 94 days.
